Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4LV, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4LV-01A (Primary Tumor).

[page 1 of 5]
Result type: Report
Result date:
Result status: Auth (Verified)
Result title: SPECIMEN DESCRIPTION
Performed by:

* Final Report *

ICD-0-3

Mesothelioma, epithelioid, NOS 90543

Site: pleura, NOS C38.4

hw
10/4/12

SPECIMEN DESCRIPTION

LEFT LUNG
LEVEL 10 LYMPH NODE
MEDIALSTINAL FAT
BRONCHIAL MARGINS
THORACOSCOPY SITE 1 POSTERIOR
THORACOSCOPY SITE 2 ANTERIOR
LEVEL 7 LYMPH NODE

SURGICAL PATHOLOGY REPORT

LOCATION: [REDACTED]

PATHOLOGY NO.: [REDACTED]

HOSPITAL ID: [REDACTED]

PATIENT ID: [REDACTED]

HOSPITAL NO.: [REDACTED]
ACCOUNT NO.: [REDACTED]
DATE RECEIVED:
DATE OF PROCEDURE:
ACCN REQ. NO.: NOT GIVEN
ATTENDING PHYS:

PATIENT'S NAME: [REDACTED]
AGE/SEX/DOB: M
PHYSICIAN(S):
COPY TO:
REFERRING PHYS:

DIAGNOSIS:

A. LEFT LUNG PNEUMONECTOMY: MALIGNANT MESOTHELIOMA, SOLID, EPITHELIOID AND SARCOMATOUS PATTERS DIFFUSELY INVOLVING THE PLEURA, PARIETAL AND VISCERAL WITH DIRECT EXTENSION INTO THE LUNG PARENCHYMA, ADHERENT TO THE DIAPHRAGM SLIGHTLY AND FOCALLY INFILTRATING THE SKELETAL MUSCLE AND ALSO INVOLVING THE MEDIAL PLEURA AND ADHERENT PARIETAL PERICARDIUM.

TUMOR EXTENDS VERY CLOSE AND AT THE MARGINS AS SEEN IN RANDOM SECTIONS.

BRONCHIAL MARGIN OF RESECTIONS NEGATIVE FOR TUMOR.

NINE REGIONAL LYMPH NODES ARE IDENTIFIED AND THEY ARE NEGATIVE FOR TUMOR. THEY SHOW SINUS HISTIOCYTOSIS, ANTHRACOTIC PIGMENTATION AND REACTIVE FOLLICULAR HYPERPLASIA. (SEE COMMENT).

B. LEVEL 10 LYMPH NODE: ONE LYMPH NODE NEGATIVE FOR TUMOR. IT SHOWS SINUS

Printed by:
Printed on:

Page 1 of 5
(Continued)

[page 2 of 5]
[REDACTED]

HISTIOCYTOSIS, ANTHRACOTIC PIGMENTATION, CONGESTION AND REACTIVE FOLLICULAR HYPERPLASIA.

C. LABELED AS MEDIASTINAL FAT: SIX LYMPH NODES ARE IDENTIFIED AND ARE NEGATIVE FOR TUMOR.

D. LABELED BRONCHIAL MARGIN: BRONCHIAL MARGIN NEGATIVE FOR TUMOR.

E. LABELED THORACOSCOPY SITE #1 POSTERIOR: SKIN WITH CUTANEOUS SCAR AND ATTACHED SKELETAL MUSCLE, NEGATIVE FOR TUMOR.

F. THORACOSCOPY SITE #2, ANTERIOR: SKIN WITH CUTANEOUS SCAR, NEGATIVE FOR TUMOR.

G. LABELED LEVEL 7 LYMPH NODES: FOUR LYMPH NODES NEGATIVE FOR TUMOR. THEY SHOW SINUS HISTIOCYTOSIS, CONGESTION, ANTHRACOTIC PIGMENTATION AND REACTIVE FOLLICULAR HYPERPLASIA.

COMMENT: The pleura (parietal and visceral) is diffusely thickened involved with malignant mesothelioma. It also involves the pleura at the diaphragmatic surface and is adherent to the diaphragm. It slightly and focally infiltrate the skeletal muscle. Medially, the pleura is also involved with tumor and it involves the adherent parietal pericardium. The tumor appears solid, made up of masses of polygonal cells and spindle cells with desmoplasia and marked chronic inflammation with areas of necrosis. There focal areas of papillary pattern. The tumor focally infiltrates into the lung parenchyma. The interlobar pleura is also involved and also here the tumor infiltrates into the lung parenchyma. The lung parenchyma shows edema, acute and chronic passive congestion, focal scattered chronic pneumonitis and moderate sclerosis of vessels. No thrombi are identified in the small and large vessels. Several lymph nodes are identified and are all negative for metastatic tumor. The nodes show sinus histiocytosis, congestion, anthracotic pigmentation and reactive follicular hyperplasia. The bronchial margin of resection is negative for tumor.

Immunostains for the tumor cells are done on two blocks to include: keratin- positive; vimentin-positive; calretinin-positive; CK5/6-positive; BER EP4- negative; B72.3- negative; CEA- negative; S100-negative, and TTF-1-negative. The results of these special stains supports the diagnosis of MESOTHELIOMA.

=====

SPECIMEN: A	LEFT LUNG
B	LEVEL 10 LYMPH NODE
C	MEDIASTINAL FAT
D	BRONCHIAL MARGINS
E	THORACOSCOPY SITE 1 POSTERIOR
F	THORACOSCOPY SITE 2 ANTERIOR
G	LEVEL 7 LYMPH NODE
OPERATION: PNEUMONECTOMY	

Printed by:
Printed on:

Page 2 of 5
(Continued)

[page 3 of 5]
PRE-OP DIAGNOSIS: MESOTHELIOMA
POST-OP DIAGNOSIS: SAME
CLINICAL DATA: NOT GIVEN

GROSS DESCRIPTION:

A. Received fresh, labeled left lung, is a 1,790 gm left pneumonectomy specimen that measures 30.0 x 23.8 x 8.0 cm, overall. The specimen includes the entire left lung and has an attached portion of diaphragm and pericardium. The pericardium is 12.0 x 11.5 cm and has a gray-pink, smooth, glistening surface. The diaphragm is 23.0 x 14.5 x 2.0 cm. The surgical resection margin surrounding the diaphragm and pericardium are inked black. The bronchial margin and vessel margin at the hilum, are taken and upon opening of both the bronchi and vessels, all are unremarkable. Eight (8) hilar lymph nodes are identified, ranging from 0.9 x 0.7 x 0.4 cm up to 1.4 x 1.2 x 0.5 cm. Upon dissection, some of the larger lymph nodes have a dark-black to gray, smooth, glistening cut surface. The parietal pleura is red-pink, smooth and upon palpation is indurated in some areas. The specimen is bivalved to reveal a gray-white, firm rim of tumor, extending into the lung parenchyma and involving the pericardium and part of the diaphragm. The tumor occupies 30% of the lung, ranges from 0.6 cm up to 8.5 cm in thickness. The interlobar fissure is involved and obliterated. The inferior aspect of the lung is remarkable for a 1.5 cm cavity, containing a clear fluid and is lined by dusky, soft, necrotic material. The uninvolved diaphragm is red and soft. The uninvolved lung parenchyma is red, soft and spongy. Representative sections are submitted in 32 cassettes.

Section summary:

- 1-2 tumor with diaphragm
- 3- tumor with pericardium
- 4- tumor with pleura
- 5- bronchial margin
- 6- artery margin
- 7- vein margin
- 8-12 tumor with pericardium (#12 includes diaphragm)
- 13-17 tumor with diaphragm (#15 includes visceral pleura; 16-17 include cavity)
- 18- tumor with parietal pleura
- 19-20 tumor with intralobar fissure
- 21- tumor with pleura
- 22-24 tumor with lung parenchyma (#22 includes hilar nodes)
- 25- two lymph nodes
- 26- two lymph nodes
- 27- half of one bisected lymph node
- 28- ~~other half of one bisected lymph node~~
- 29-31- one bisected lymph node, each
- 32- viscera, parietal pleura with tumor and lung parenchyma.
- NOTE: Additional sections consisting of the tumor with pleural surface is submitted in cassettes add 1-5.

B. Received fresh, labeled level 10 lymph node, is a 1.7 x 1.4 x 0.3 cm red-pink, soft lymph node, which has a scant amount of attached soft tissue.

Printed by:
Printed on:

Page 3 of 5
(Continued)

[page 4 of 5]
[REDACTED]

The specimen is bisected to reveal a dark-red, congested cut surface. The lymph node is entirely submitted in 1 cassette.

C. Received fresh, labeled mediastinal fat, is a 4.3 x 3.5 x 1.0 cm soft, lobulated portion of adipose tissue. Dissection reveals six (6) possible lymph nodes, ranging from 0.4 cm up to 1.0 x 0.6 x 0.4 cm. Two (2) of the lymph nodes are sectioned to reveal purple-pink, smooth and glistening cut surfaces. Lymph nodes are entirely submitted in 3 cassettes labeled C, as follows:

- 1- one bisected lymph node
- 2- two possible lymph node
- 3- three lymph nodes.

D. Received fresh, labeled bronchial margin, is a pink-yellow, rubbery tubular structure, consistent with portion of bronchus which is 2.1 cm in length and 1.7 cm in diameter. Along one aspect, is a staple line which is 3.0 cm in length. The specimen is trisected and submitted entirely in 3 cassettes labeled D (region adjacent to staples is in cassette #1).

E. Received fresh, labeled thoracoscopy site #1, posterior, is a 7.5 x 2.0 cm tan ellipse of hair-bearing skin, that is excised to a depth ranging from 1.5 cm up to 3.0 cm. The deep margin consists of possible brown-red, skeletal muscle that is 2.8 x 1.6 x 1.5 cm. The surgical resection margin is inked black. The specimen is serially sectioned to reveal lobulated adipose tissue with interspersed gray, fibrous tissue and skeletal muscle at the deep margin. No lesions are identified, grossly. Representative sections submitted in three cassettes labeled E (one full thickness section cut in half in cassette #1-2).

F. Received fresh, labeled thoracoscopy site #2, anterior, is a 4.3 x 1.7 cm brown ellipse of hair-bearing skin, that is excised to a depth of 2.3 cm. The skin surface is remarkable for a 1.6 cm possible well-healed scar. The surgical resection margin is inked black. The specimen is serially sectioned to reveal yellow, lobulated, soft cut surfaces with interspersed gray, fibrous tissue. Representative sections submitted in three cassettes labeled F.

G. Received fresh, labeled level 7 lymph node, are four (4) gray-black, soft, irregular lymph nodes, ranging from 1.4 x 1.3 x 0.5 cm up to 4.0 x 2.0 x 0.7 cm. The lymph nodes are bisected to reveal dark-black, gray, mottled, smooth and glistening cut surfaces. The smaller lymph nodes are entirely submitted and reps of larger lymph node submitted in 5 cassettes labeled G, as follows:
1-3 one bisected lymph node, each
4-5 reps of largest lymph node.

CPT CODE: [REDACTED]

ELECTRONIC SIGNATURE: [REDACTED]

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Completed Action List:

* Perform by

Printed by:

Printed on:

Page 5 of 5
(End of Report)

11PAA Discrepancy		☒

9/23/12

Source: NCI Genomic Data Commons file 87d3c07b-c538-4edb-8a79-7ab70771213f (TCGA-MQ-A4LV.B58C2E00-6E35-4A56-AF0D-0A62335BBD89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).